Somatic mutation profile of tumor specimen C3N-01339-01 (aliquot CPT0094490010) from CPTAC case C3N-01339, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 68.6 years (25,041 days).
Specimen C3N-01339-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ac8a4b6-1ff3-42c9-9643-c7a0826ccdf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01339-31 (Blood Derived Normal), aliquot CPT0094550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/809a070e-3db1-4b55-8252-9113c525c1a3

The open-access MAF lists 302 somatic variants for this specimen: 192 protein-altering or splice-affecting, 73 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 73, Intron 14, Nonsense Mutation 11, Frame Shift Del 9, 5'Flank 8, 3'UTR 6, RNA 5, Splice Site 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 390/450 reads (87%) | catalogued as rs121913382, COSV58682685, COSV58683250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.358A>T p.K120* | Nonsense Mutation (SNP) | VAF 267/302 reads (88%) | hotspot (GDC flag); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.406T>G p.F136V (on ENST00000326724 / NM_001080395.3; = p.F33V on NM_004920.2) | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359369793; called by muse, mutect2, varscan2
- ABCC8 | c.2220C>A p.S740R | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV56849703; called by muse, mutect2, varscan2
- ADAMTS16 | c.2996C>G p.S999* | Nonsense Mutation (SNP) | VAF 28/386 reads (7%) | catalogued as COSV56979513, COSV99940616; called by muse, mutect2
- AP2A1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 106/124 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV62818635; called by muse, mutect2, varscan2
- ARHGEF18 | c.2699G>A p.R900H (on ENST00000359920 / NM_001130955.2; = p.R796H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1474842329; called by muse, varscan2
- ATP6V0A4 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 248/303 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760974203; called by muse, mutect2, varscan2
- B4GALNT1 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1008314263; called by muse, mutect2
- BAZ1A | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62409122; called by muse, mutect2, varscan2
- BEND3 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 161/282 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV64682576; called by muse, mutect2, varscan2
- BORCS5 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 458/952 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); catalogued as rs150829239; called by muse, mutect2, varscan2
- CASP8AP2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs745563258, COSV99386732; called by muse, mutect2, varscan2
- CASR | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.235); catalogued as COSV56139497; called by muse, mutect2, varscan2
- CHERP | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1164769454, COSV52226331; called by muse, mutect2, varscan2
- COL11A1 | c.3229C>A p.P1077T | Missense Mutation (SNP) | VAF 260/325 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs144562769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.2323C>A p.L775I | Missense Mutation (SNP) | VAF 122/450 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100307896; called by muse, mutect2, varscan2
- DISP1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 64/714 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs146408462; called by muse, mutect2
- DMD | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs754158494, COSV99927482; called by muse, mutect2, varscan2
- DOCK10 | c.3185G>A p.R1062H | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753305029; called by muse, mutect2, varscan2
- DRD2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779267865, COSV60757661; called by muse, mutect2
- DUS1L | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV57648319; called by muse, mutect2, varscan2
- ELMO2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs776816963, COSV51684095; called by muse, mutect2, varscan2
- ENPP7 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs782027824; called by muse, mutect2, varscan2
- EPB41L4A | c.965G>T p.S322I | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV54878644; called by muse, mutect2, varscan2
- ESYT3 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs762014244; called by muse, mutect2, varscan2
- FBF1 | c.1005_1014del p.I336Gfs*86 (on ENST00000586717; = p.I350Gfs*86 on NM_001319193.1) | Frame Shift Del (DEL) | VAF 104/298 reads (35%) | catalogued as rs1320999919; called by mutect2, varscan2
- FGG | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 135/187 reads (72%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); catalogued as rs747963231, COSV100271799; called by muse, mutect2, varscan2
- FGG | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60194425; called by muse, mutect2, varscan2
- FRG2B | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 86/672 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV71042715; called by muse, mutect2
- FSCB | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61218690; called by muse, mutect2, varscan2
- GPR174 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs995300950; called by muse, mutect2
- IQSEC1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 172/225 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1349493270, COSV56229692; called by muse, mutect2, varscan2
- ITSN2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1194506232; called by muse, mutect2, varscan2
- KIF25 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63028032; called by muse, mutect2, varscan2
- KMT2A | c.8110C>T p.R2704W | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1437799270, COSV63294739; called by muse, mutect2
- KMT2D | c.9631del p.E3211Kfs*10 | Frame Shift Del (DEL) | VAF 186/383 reads (49%) | catalogued as COSV56412763; called by mutect2, pindel, varscan2
- LRP2 | c.4987C>T p.R1663C | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs898681788, COSV55553067, COSV99787664; called by muse, mutect2, varscan2
- MAGEB18 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV57465063; called by muse, mutect2
- MC3R | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99710814; called by muse, mutect2, varscan2
- MID1 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs763101201; called by muse, mutect2, varscan2
- MPDU1 | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 334/646 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1259380344; called by muse, mutect2, varscan2
- MROH2B | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs766752694, COSV68186705, COSV68187077; called by muse, mutect2
- MYOM2 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 83/215 reads (39%) | catalogued as rs201853007, COSV100036536; called by muse, mutect2, varscan2
- NAA30 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100035950; called by muse, mutect2, varscan2
- NMD3 | c.981A>G p.I327M | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1189866106, COSV100664535; called by muse, mutect2, varscan2
- NOVA1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1042740142, COSV57478679; called by muse, mutect2, varscan2
- NOXO1 | c.845G>C p.R282P (on ENST00000397280 / NM_172168.3; = p.R276P on NM_144603.4) | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs776291285, COSV50191345; called by muse, mutect2, varscan2
- P3H4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1555615317; called by muse, mutect2, varscan2
- PASK | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52148853; called by muse, mutect2, varscan2
- PLCE1 | c.2566G>A p.D856N | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs764021031, COSV53349353; called by muse, mutect2, varscan2
- PPEF1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs767043387, COSV100583860; called by muse, mutect2, varscan2
- PPP6R1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 106/129 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1244664621; called by muse, mutect2, varscan2
- REG3G | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 149/247 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1356943617; called by muse, mutect2, varscan2
- SEC16A | c.3500A>T p.D1167V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51540393; called by muse, mutect2, varscan2
- SLC26A7 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs764996558, COSV52586992; called by muse, mutect2, varscan2
- SLC9A1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs770741822; called by muse, mutect2, varscan2
- SLITRK4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs997536820, COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SNW1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99834487; called by muse, mutect2, varscan2
- SPAG6 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs866463670; called by muse, mutect2, varscan2
- SPTBN1 | c.3910G>A p.D1304N | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV61685323; called by muse, mutect2
- SYNGR1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 68/622 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.624); catalogued as COSV100198294; called by muse, mutect2, varscan2
- TAOK3 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1277510978, COSV101183685; called by muse, mutect2, varscan2
- TCF25 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528966; called by muse, mutect2, varscan2
- TXNDC16 | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1310074667, COSV55984621; called by muse, mutect2, varscan2
- UQCRHL | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570054582, COSV72331550; called by muse, mutect2
- UQCRHL | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 55/574 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs878911951, COSV72331555; called by muse, mutect2
- UQCRHL | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 92/539 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1049258, COSV72331696; called by muse, varscan2
- VPS54 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 135/216 reads (63%) | catalogued as COSV55443633; called by muse, mutect2, varscan2
- ZIC4 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 41/444 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs916708888, COSV67172681, COSV67173104; called by muse, mutect2
- ZNF708 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs770830441, COSV63606861; called by muse, mutect2, varscan2
- ZNF821 | c.854G>A p.R285Q (on ENST00000425432 / NM_001376297.1; = p.R243Q on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57987674; called by muse, mutect2, varscan2
- ABCA13 | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADCY7 | c.1258A>C p.T420P | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRB1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF3 | c.2105C>A p.S702Y | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- AGAP1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANAPC2 | c.1717A>T p.N573Y | Missense Mutation (SNP) | VAF 210/450 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANK3 | c.12885A>C p.E4295D (on ENST00000280772 / NM_001320874.2; = p.E919D on NM_001149.3) | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2
- AQP12B | c.73T>G p.S25A | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGEF3 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, varscan2
- ARMCX3 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATM | c.2323T>C p.S775P | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- BBS9 | c.1897G>T p.A633S (on ENST00000242067 / NM_001348036.1; = p.A593S on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMP15 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 183/316 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C6 | c.1142T>G p.F381C | Missense Mutation (SNP) | VAF 68/573 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CACNA1F | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 179/373 reads (48%) | called by muse, mutect2, varscan2
- CAMK1 | c.746-8_746-7delinsA | Splice Region (DEL) | VAF 62/184 reads (34%) | called by pindel, varscan2*
- CAMSAP2 | c.2404G>T p.V802L (on ENST00000236925 / NM_001297707.2; = p.V791L on NM_203459.3) | Missense Mutation (SNP) | VAF 166/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC141 | c.3617A>T p.Y1206F | Missense Mutation (SNP) | VAF 135/339 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CCDC141 | c.2306T>A p.I769N | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CCDC182 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCDC42 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by muse, mutect2
- CCNB1IP1 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 41/377 reads (11%) | called by muse, mutect2, varscan2
- CCND1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- CDC14C | c.825C>A p.N275K (on ENST00000428251; = p.N168K on NM_152627.3) | Missense Mutation (SNP) | VAF 202/506 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- CEP19 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFHR5 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 52/630 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- CLMN | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- COG4 | c.1731C>G p.F577L | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.089); called by muse, mutect2
- COL22A1 | c.686A>C p.E229A | Missense Mutation (SNP) | VAF 87/381 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- COL6A3 | c.3748T>G p.Y1250D | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COQ6 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPA4 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 190/249 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRB2 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 112/193 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CST9 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 57/932 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- CUL7 | c.3452T>C p.V1151A | Missense Mutation (SNP) | VAF 377/496 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL9 | c.3547A>T p.S1183C | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CUX2 | c.3199C>A p.Q1067K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DCT | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DICER1 | c.5206C>T p.R1736W | Missense Mutation (SNP) | VAF 53/470 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- E4F1 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EHD3 | c.1265T>C p.F422S | Missense Mutation (SNP) | VAF 121/207 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP300 | c.6614del p.M2205Rfs*38 | Frame Shift Del (DEL) | VAF 76/728 reads (10%) | called by mutect2, pindel
- FAAH2 | c.1597T>C p.*533Qext*7 | Nonstop Mutation (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2
- FAM13B | c.1690A>T p.R564* | Nonsense Mutation (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- FCAMR | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.1777T>A p.S593T | Missense Mutation (SNP) | VAF 119/943 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FRG2C | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 106/875 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- GABRA2 | c.633T>A p.D211E | Missense Mutation (SNP) | VAF 163/222 reads (73%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLE1 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 18/579 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- GOLGA6L10 | c.1165A>T p.R389W | Missense Mutation (SNP) | VAF 266/1186 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.124); called by mutect2, varscan2
- GOLGA8F | c.441G>T p.E147D (on ENST00000526619; = p.E353D on NM_001350920.2) | Missense Mutation (SNP) | VAF 446/1924 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.116); called by muse, varscan2
- HERC6 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 112/145 reads (77%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HIF3A | c.535C>T p.L179F (on ENST00000377670 / NM_152795.4; = p.L110F on NM_022462.4) | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- INAVA | c.798C>G p.S266R | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ISLR | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ITPR2 | c.7561G>T p.D2521Y | Missense Mutation (SNP) | VAF 135/288 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ16 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- KIAA1614 | c.1619dup p.S541Qfs*79 | Frame Shift Ins (INS) | VAF 68/109 reads (62%) | called by mutect2, pindel, varscan2
- KL | c.1520C>A p.P507H | Missense Mutation (SNP) | VAF 110/302 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRP1B | c.10493A>G p.Q3498R | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- LRRN2 | c.1927G>C p.A643P | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MAGEC1 | c.2675C>T p.T892I | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- MAP3K15 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.09); called by muse, mutect2, varscan2
- MAPKAPK3 | c.676T>C p.W226R | Missense Mutation (SNP) | VAF 152/208 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCO | c.1430-1G>T p.X477_splice | Splice Site (SNP) | VAF 145/386 reads (38%) | called by muse, mutect2, varscan2
- MCM9 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCMDC2 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MTF1 | c.770del p.K257Sfs*54 | Frame Shift Del (DEL) | VAF 82/105 reads (78%) | called by mutect2, varscan2
- MTX1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.017); called by muse, mutect2
- MUC5B | c.12064dup p.H4022Pfs*51 | Frame Shift Ins (INS) | VAF 89/406 reads (22%) | called by mutect2, pindel, varscan2
- MYH11 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 173/260 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOC | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- NAT10 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 91/129 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPD3 | c.3627G>T p.K1209N | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHEJ1 | c.638del p.N213Ifs*42 | Frame Shift Del (DEL) | VAF 169/513 reads (33%) | called by mutect2, pindel, varscan2
- NKX2-6 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 165/501 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPAP1 | c.1885del p.H629Tfs*40 | Frame Shift Del (DEL) | VAF 324/639 reads (51%) | called by mutect2, pindel, varscan2
- NSD1 | c.2536del p.T846Pfs*7 | Frame Shift Del (DEL) | VAF 154/252 reads (61%) | called by mutect2, pindel, varscan2
- OR4C11 | c.442A>C p.I148L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4Q3 | c.310dup p.S104Ffs*17 | Frame Shift Ins (INS) | VAF 114/314 reads (36%) | called by mutect2, pindel, varscan2
- OR5B2 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OSR1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 258/306 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- PANK4 | c.1871A>G p.N624S | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PCDHGA12 | c.2438del p.N813Tfs*39 | Frame Shift Del (DEL) | VAF 196/311 reads (63%) | called by mutect2, pindel, varscan2
- PKD1 | c.9179G>A p.S3060N | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLDIP2 | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 63/198 reads (32%) | called by muse, mutect2, varscan2
- PPP1R12A | c.2666+1G>A p.X889_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- PTPRE | c.1324A>T p.N442Y | Missense Mutation (SNP) | VAF 164/241 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PYHIN1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.102); called by muse, mutect2
- RAB7A | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 89/751 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RGSL1 | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 205/232 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPN1 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 137/526 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SECISBP2L | c.1381G>A p.E461K (on ENST00000559471 / NM_001193489.2; = p.E416K on NM_014701.4) | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA5A | c.3074T>G p.L1025R | Missense Mutation (SNP) | VAF 21/545 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2
- SLC10A7 | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 154/203 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC1A2 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 125/162 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A8 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 154/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLC24A3 | c.1745T>C p.I582T | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SLC38A5 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- SNX31 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SORCS1 | c.2626G>T p.G876C | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX3 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SPTB | c.4156C>A p.Q1386K | Missense Mutation (SNP) | VAF 80/689 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SSC5D | c.1978C>A p.L660I | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SSX2IP | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- SYN1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SYTL1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 83/113 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SYTL5 | c.904del p.R302Afs*10 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- TAS2R14 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 16/538 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- TDRD15 | c.5779A>T p.T1927S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- TECTA | c.3277C>G p.Q1093E | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TXNRD3 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- USP48 | c.1963+6C>T | Splice Region (SNP) | VAF 92/132 reads (70%) | called by muse, mutect2, varscan2
- VCAN | c.5398G>T p.E1800* | Nonsense Mutation (SNP) | VAF 61/356 reads (17%) | called by muse, mutect2, varscan2
- WIPF1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- XKR3 | c.1093T>G p.F365V | Missense Mutation (SNP) | VAF 242/467 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- YLPM1 | c.1709C>G p.P570R | Missense Mutation (SNP) | VAF 130/350 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZBTB46 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF257 | c.1019_1033del p.G340_Q345delinsE | In Frame Del (DEL) | VAF 79/256 reads (31%) | called by mutect2, pindel, varscan2
- ZNF653 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 147/404 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAM15 | c.474G>A p.G158= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- AGTPBP1 | c.1947C>T p.P649= (on ENST00000357081 / NM_001330701.2; = p.P609= on NM_015239.2) | Silent (SNP) | VAF 108/223 reads (48%) | catalogued as rs376158351; called by muse, mutect2, varscan2
- AMZ1 | c.63G>C p.L21= | Silent (SNP) | VAF 93/368 reads (25%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.840G>A p.E280= | Silent (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2, varscan2
- AUP1 | c.756G>A p.L252= | Silent (SNP) | VAF 198/358 reads (55%) | called by muse, mutect2, varscan2
- BABAM2 | c.825T>C p.I275= | Silent (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- BAIAP3 | c.3105G>A p.A1035= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs772799963, COSV99136413; called by muse, mutect2, varscan2
- CCDC110 | c.594T>C p.N198= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as rs1453880961; called by muse, mutect2, varscan2
- CDH10 | c.2061G>T p.R687= | Silent (SNP) | VAF 326/1045 reads (31%) | catalogued as COSV52571026, COSV52573259; called by muse, mutect2, varscan2
- CELSR1 | c.7767G>A p.A2589= | Silent (SNP) | VAF 90/159 reads (57%) | catalogued as rs777063463; called by muse, mutect2, varscan2
- CTNNA2 | c.81G>C p.L27= | Silent (SNP) | VAF 44/307 reads (14%) | catalogued as COSV63563287; called by muse, mutect2, varscan2
- CYP1A2 | c.1527G>A p.A509= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as rs771395182, COSV59661115; called by muse, mutect2
- DACT1 | c.1122G>A p.G374= | Silent (SNP) | VAF 204/476 reads (43%) | called by muse, mutect2, varscan2
- DLG5 | c.2958C>A p.P986= | Silent (SNP) | VAF 184/336 reads (55%) | catalogued as rs1458617174; called by muse, mutect2, varscan2
- EDNRB | c.966G>C p.L322= (on ENST00000377211 / NM_001201397.1; = p.L232= on NM_000115.5) | Silent (SNP) | VAF 65/330 reads (20%) | called by muse, mutect2, varscan2
- EPDR1 | c.252G>A p.A84= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs1463035623; called by muse, mutect2
- ERBB4 | c.486T>C p.H162= | Silent (SNP) | VAF 87/436 reads (20%) | catalogued as COSV53541671; called by muse, mutect2, varscan2
- ERCC6L | c.2925T>G p.V975= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- FANCI | c.3561C>T p.S1187= (on ENST00000310775 / NM_001376911.1; = p.S1127= on NM_018193.3) | Silent (SNP) | VAF 180/565 reads (32%) | catalogued as rs748619003; called by muse, varscan2
- FGF23 | c.369G>T p.G123= | Silent (SNP) | VAF 41/1256 reads (3%) | catalogued as COSV52975397; called by muse, mutect2
- FKBP9 | c.1638C>T p.D546= | Silent (SNP) | VAF 95/466 reads (20%) | catalogued as rs751182422; called by muse, mutect2, varscan2
- FSIP1 | c.801C>T p.N267= | Silent (SNP) | VAF 87/195 reads (45%) | catalogued as rs1332902575; called by muse, mutect2, varscan2
- G6PD | c.810G>A p.L270= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs781811771, COSV63702976; called by muse, mutect2, varscan2
- GAB2 | c.414C>T p.P138= (on ENST00000361507 / NM_080491.3; = p.P100= on NM_012296.3) | Silent (SNP) | VAF 254/448 reads (57%) | catalogued as COSV60865869; called by muse, mutect2, varscan2
- GABRB3 | c.321G>A p.T107= | Silent (SNP) | VAF 115/759 reads (15%) | catalogued as rs367761610; called by muse, mutect2, varscan2
- GALC | c.57G>A p.A19= | Silent (SNP) | VAF 104/217 reads (48%) | called by muse, mutect2, varscan2
- GJA5 | c.717C>G p.V239= | Silent (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2, varscan2
- GJB4 | c.372G>A p.R124= | Silent (SNP) | VAF 348/432 reads (81%) | catalogued as COSV58355856; called by muse, mutect2, varscan2
- GREM2 | c.235C>A p.R79= | Silent (SNP) | VAF 199/224 reads (89%) | catalogued as rs149299291; called by muse, mutect2, varscan2
- GRM7 | c.1717C>A p.R573= | Silent (SNP) | VAF 134/169 reads (79%) | catalogued as COSV63130808; called by muse, mutect2, varscan2
- HPSE2 | c.432C>G p.L144= | Silent (SNP) | VAF 195/265 reads (74%) | catalogued as COSV100985448; called by muse, mutect2, varscan2
- INF2 | c.18C>T p.G6= | Silent (SNP) | VAF 63/213 reads (30%) | catalogued as rs1032255653, COSV100402613; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ITGA2B | c.1062C>T p.A354= | Silent (SNP) | VAF 44/416 reads (11%) | catalogued as rs1245234436, COSV99289089; called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 60/100 reads (60%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- KIAA1958 | c.771A>G p.T257= | Silent (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- KLHL25 | c.87G>A p.P29= | Silent (SNP) | VAF 42/301 reads (14%) | catalogued as rs200944201; called by muse, mutect2, varscan2
- LIG1 | c.474G>A p.E158= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- LRRTM3 | c.490T>C p.L164= | Silent (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- MED27 | c.852C>T p.C284= | Silent (SNP) | VAF 27/276 reads (10%) | catalogued as rs750350301; called by muse, mutect2, varscan2
- MORC1 | c.876A>C p.A292= | Silent (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- MUC12 | c.13458T>A p.P4486= (on ENST00000379442; = p.P4343= on NM_001164462.1) | Silent (SNP) | VAF 149/1139 reads (13%) | catalogued as rs1287874879; called by muse, mutect2, varscan2
- MYO7B | c.4812C>A p.P1604= | Silent (SNP) | VAF 84/244 reads (34%) | called by muse, mutect2, varscan2
- NEXMIF | c.2769C>A p.S923= | Silent (SNP) | VAF 54/336 reads (16%) | called by muse, mutect2, varscan2
- NOP14 | c.354C>T p.I118= | Silent (SNP) | VAF 133/164 reads (81%) | catalogued as rs747459687; called by muse, mutect2, varscan2
- OGDH | c.1062T>C p.Y354= | Silent (SNP) | VAF 92/331 reads (28%) | called by muse, mutect2, varscan2
- PDE6B | c.1461A>G p.E487= | Silent (SNP) | VAF 169/383 reads (44%) | called by muse, mutect2, varscan2
- PLSCR5 | c.762T>A p.G254= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as rs919261359; called by muse, mutect2, varscan2
- PPRC1 | c.3882G>A p.G1294= | Silent (SNP) | VAF 90/117 reads (77%) | catalogued as rs907958253; called by muse, mutect2, varscan2
- PRUNE2 | c.1113C>T p.A371= | Silent (SNP) | VAF 126/270 reads (47%) | catalogued as rs1003569406; called by muse, mutect2, varscan2
- PTPRR | c.160C>T p.L54= | Silent (SNP) | VAF 238/485 reads (49%) | called by muse, varscan2
- RAB37 | c.282C>T p.S94= (on ENST00000392613 / NM_001006638.3; = p.S87= on NM_175738.5) | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as rs763968925, COSV100463611; called by muse, mutect2, varscan2
- RCC1 | c.561G>A p.L187= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as COSV65779871; called by muse, mutect2, varscan2
- RELL2 | c.729G>A p.R243= | Silent (SNP) | VAF 214/277 reads (77%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.774A>C p.S258= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- SCN9A | c.561G>A p.P187= | Silent (SNP) | VAF 75/436 reads (17%) | catalogued as rs200182914; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC17A1 | c.16C>A p.R6= | Silent (SNP) | VAF 82/104 reads (79%) | catalogued as rs550260424; called by muse, mutect2, varscan2
- SLC35F6 | c.285G>T p.A95= | Silent (SNP) | VAF 121/208 reads (58%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1065G>C p.L355= | Silent (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- SPINK1 | c.138C>T p.V46= | Silent (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- SPTAN1 | c.5262C>T p.A1754= | Silent (SNP) | VAF 21/604 reads (3%) | called by muse, mutect2
- SYCP2 | c.1281C>A p.I427= | Silent (SNP) | VAF 54/184 reads (29%) | called by muse, mutect2, varscan2
- TENM1 | c.7938G>A p.V2646= | Silent (SNP) | VAF 168/221 reads (76%) | called by muse, mutect2, varscan2
- TG | c.7176C>A p.A2392= | Silent (SNP) | VAF 171/357 reads (48%) | called by muse, mutect2, varscan2
- TIMP1 | c.564C>G p.A188= | Silent (SNP) | VAF 140/230 reads (61%) | called by muse, mutect2, varscan2
- TLR6 | c.1296G>T p.V432= | Silent (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- TSKS | c.975C>T p.T325= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as rs762305803, COSV99882985; called by muse, mutect2, varscan2
- TTN | c.58362G>A p.P19454= (on ENST00000591111; = p.P12030= on NM_003319.4) | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs760168563, COSV100612660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UQCRHL | c.231A>G p.A77= | Silent (SNP) | VAF 49/368 reads (13%) | catalogued as rs10722, COSV72331553; called by muse, mutect2
- VCAM1 | c.1071G>A p.G357= | Silent (SNP) | VAF 128/179 reads (72%) | catalogued as COSV54121158; called by muse, mutect2, varscan2
- XIAP | c.264A>C p.P88= | Silent (SNP) | VAF 51/483 reads (11%) | called by muse, mutect2, varscan2
- ZNF44 | c.1095G>A p.A365= (on ENST00000356109 / NM_001164276.2; = p.A317= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 83/209 reads (40%) | catalogued as rs373578837; called by muse, mutect2, varscan2
- ZNF469 | c.6087C>T p.S2029= (on ENST00000437464; = p.S2057= on NM_001367624.2) | Silent (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- ZNF697 | c.1374G>C p.V458= | Silent (SNP) | VAF 74/87 reads (85%) | called by muse, mutect2, varscan2
- AC011294.1 | n.307A>T | RNA (SNP) | VAF 21/158 reads (13%) | catalogued as rs747239692; called by muse, mutect2, varscan2
- AC093582.1 | n.206A>G | RNA (SNP) | VAF 90/358 reads (25%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23977801 G>A | 5'Flank (SNP) | VAF 42/195 reads (22%) | called by muse, mutect2, varscan2
- ALG12 | c.*2G>A | 3'UTR (SNP) | VAF 42/303 reads (14%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2313+1538G>T | Intron (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502279 ins T | 5'Flank (INS) | VAF 72/236 reads (31%) | called by mutect2, varscan2
- ARPP21 | c.795+430G>C | Intron (SNP) | VAF 138/179 reads (77%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39723C>A | Intron (SNP) | VAF 52/249 reads (21%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39722C>T | Intron (SNP) | VAF 53/253 reads (21%) | called by muse, mutect2, varscan2
- C12orf43 | c.146-1321C>T | Intron (SNP) | VAF 139/278 reads (50%) | catalogued as rs543687135; called by muse, mutect2, varscan2
- C14orf132 | chr14:96090785 G>A | 3'Flank (SNP) | VAF 39/370 reads (11%) | catalogued as rs914818606, COSV101402393; called by muse, mutect2
- COQ5 | chr12:120529164 C>T | 5'Flank (SNP) | VAF 34/262 reads (13%) | called by muse, mutect2, varscan2
- DACH2 | c.1240+2844G>T | Intron (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- DNM1L | chr12:32679237 G>T | 5'Flank (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- DST | c.153+43T>G | Intron (SNP) | VAF 99/284 reads (35%) | called by muse, mutect2, varscan2
- FAM183BP | n.1071C>A | RNA (SNP) | VAF 77/637 reads (12%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643755 A>T | 5'Flank (SNP) | VAF 50/152 reads (33%) | called by mutect2, varscan2
- IGHD1-1 | chr14:105922612 C>A | 5'Flank (SNP) | VAF 106/380 reads (28%) | catalogued as rs1555402840; called by mutect2, varscan2
- LAMTOR1 | c.*57C>T | 3'UTR (SNP) | VAF 46/147 reads (31%) | catalogued as rs543375424; called by muse, mutect2, varscan2
- MAJIN | c.*13C>T | 3'UTR (SNP) | VAF 28/288 reads (10%) | catalogued as rs762628309; called by muse, mutect2
- MAJIN | c.473+1241G>A | Intron (SNP) | VAF 79/177 reads (45%) | called by muse, mutect2, varscan2
- MIR6080 | chr17:64780391 G>A | 5'Flank (SNP) | VAF 64/191 reads (34%) | catalogued as rs970705905; called by muse, mutect2, varscan2
- PKD1L2 | n.562C>T | RNA (SNP) | VAF 139/304 reads (46%) | called by muse, mutect2, varscan2
- PXDC1 | c.257-713G>A | Intron (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- RPL10 | c.492+18C>T | Intron (SNP) | VAF 137/733 reads (19%) | called by muse, mutect2, varscan2
- SLC2A1 | c.867+118T>C | Intron (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- SLC66A3 | chr2:11155198 del G | 5'Flank (DEL) | VAF 45/66 reads (68%) | called by mutect2, pindel, varscan2
- STON1 | c.-93G>T | 5'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- SUN3 | c.*49G>A | 3'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, varscan2
- TIMP1 | c.453+316G>T | Intron (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- TLX1NB | n.1498C>A | RNA (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- TMEM179 | c.522+74C>T | Intron (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- UQCRB | c.259-182C>T | Intron (SNP) | VAF 109/439 reads (25%) | catalogued as rs1385123505; called by muse, mutect2, varscan2
- XIAP | c.*2699T>C | 3'UTR (SNP) | VAF 52/551 reads (9%) | called by muse, mutect2
- XIAP | c.*5439G>T | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ZIC4 | c.-8G>C | 5'UTR (SNP) | VAF 50/287 reads (17%) | called by muse, mutect2, varscan2
- ZNF625 | chr19:12142504 T>A | 3'Flank (SNP) | VAF 91/277 reads (33%) | called by muse, mutect2, varscan2
